Somatic mutation profile of tumor specimen TCGA-91-A4BD-01A (aliquot TCGA-91-A4BD-01A-11D-A24D-08) from TCGA case TCGA-91-A4BD, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 78.1 years (28,544 days).
Specimen TCGA-91-A4BD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 29ef1b63-e1a7-405b-98a9-026de5d27ec2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-91-A4BD-10A (Blood Derived Normal), aliquot TCGA-91-A4BD-10A-01D-A24F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/de548eba-a556-440e-a7d1-8a116bfb5cbd

The open-access MAF lists 23 somatic variants for this specimen: 16 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 6, RNA 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ADCY9 | c.662T>C p.V221A | Missense Mutation (SNP) | VAF 32/113 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.76); catalogued as COSV99569371; called by muse, mutect2, varscan2
- CHST8 | c.1220A>G p.Y407C | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99380679; called by muse, mutect2, varscan2
- FBXW12 | c.1012G>A p.A338T | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as COSV99601443; called by muse, mutect2, varscan2
- GRID2 | c.121G>A p.D41N | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.179); catalogued as COSV99937439; called by muse, mutect2
- IL10RB | c.352A>T p.M118L | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV99269776; called by muse, mutect2, varscan2
- LCT | c.1597C>T p.R533C | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1447178344, COSV104384170, COSV99928573; called by muse, mutect2, varscan2
- MGA | c.2848C>T p.Q950* | Nonsense Mutation (SNP) | VAF 14/72 reads (19%) | catalogued as COSV54949413; called by muse, mutect2, varscan2
- NPTN | c.844A>G p.I282V | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV99766289; called by muse, mutect2, varscan2
- OR10H2 | c.223G>A p.V75M | Missense Mutation (SNP) | VAF 34/144 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.283); catalogued as rs751844869, COSV59945682; called by muse, mutect2, varscan2
- OR52K2 | c.725C>A p.T242K | Missense Mutation (SNP) | VAF 42/150 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as COSV57835965; called by muse, mutect2, varscan2
- RGMA | c.380G>A p.R127H | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.921); catalogued as rs373659425; called by muse, mutect2, varscan2
- TMEM120A | c.755G>A p.G252D | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100115475; called by muse, mutect2, varscan2
- WFDC10A | c.71G>A p.R24H | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs369507208; called by muse, mutect2, varscan2
- XIRP1 | c.2182T>C p.F728L | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as COSV100453375; called by muse, mutect2, varscan2
- ZNF331 | c.775A>T p.I259F | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV99466855; called by muse, mutect2, varscan2
- FADS3 | c.858G>A p.A286= | Silent (SNP) | VAF 15/58 reads (26%) | catalogued as rs369043120; called by muse, mutect2, varscan2
- FAM117A | c.798C>T p.N266= | Silent (SNP) | VAF 18/76 reads (24%) | catalogued as COSV99544461; called by muse, mutect2, varscan2
- IKZF1 | c.450C>T p.C150= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as rs772322516, COSV58780242; called by muse, mutect2, varscan2
- KDM2A | c.3255C>T p.L1085= | Silent (SNP) | VAF 20/123 reads (16%) | catalogued as COSV100445388; called by muse, mutect2, varscan2
- KRT14 | c.969G>A p.L323= | Silent (SNP) | VAF 28/143 reads (20%) | catalogued as COSV99390896; called by muse, mutect2, varscan2
- TNFAIP2 | c.663C>T p.G221= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV100280827; called by muse, mutect2
- UBTFL2 | n.484G>C | RNA (SNP) | VAF 5/28 reads (18%) | called by muse, mutect2, varscan2
